Somatic mutation profile of cancer-model specimen HCM-BROD-0419-C71-85A (3D Neurosphere, passage 7; aliquot HCM-BROD-0419-C71-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0419-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.4 years (26,453 days).
Specimen HCM-BROD-0419-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b2cf946-a3b3-4c89-b4bd-ef9b1594a3d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0419-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0419-C71-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3940ddb2-f8e7-4afc-99f6-6637346a089d

The open-access MAF lists 120 somatic variants for this specimen: 77 protein-altering or splice-affecting, 39 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 39, Splice Site 3, Splice Region 2, Intron 2, Nonsense Mutation 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.165-1G>C p.X55_splice | Splice Site (SNP) | VAF 34/34 reads (100%) | catalogued as rs786203847, CS110220, COSV64291262, COSV64292036, COSV64304032; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 258/259 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 388/775 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1568265204; called by muse, mutect2, varscan2
- ANKEF1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 65/544 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.11); catalogued as rs528690112, COSV65692046; called by muse, mutect2, varscan2
- APOB | c.3711G>T p.W1237C | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM083480, COSV51948330; called by muse, mutect2
- ARMC5 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 27/418 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1459461259; called by muse, mutect2
- ASTN2 | c.2275G>T p.G759C (on ENST00000313400 / NM_001365069.1; = p.G708C on NM_014010.5) | Missense Mutation (SNP) | VAF 59/630 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57758457, COSV57818754; called by muse, mutect2
- CYP26B1 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 242/447 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs985441611; called by muse, mutect2, varscan2
- DEPDC5 | c.3396G>A p.Q1132= (on ENST00000400246; = p.Q1201= on NM_014662.5) | Splice Region (SNP) | VAF 189/190 reads (99%) | catalogued as COSV56699607; called by muse, mutect2, varscan2
- DNAAF3 | c.64G>A p.A22T (on ENST00000524407 / NM_001256715.2; = p.A69T on NM_178837.4) | Missense Mutation (SNP) | VAF 202/481 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749669998; called by muse, mutect2, varscan2
- EGF | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 57/57 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs554205393, COSV54479134, COSV54480236; called by muse, mutect2, varscan2
- ESR1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 265/520 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753014570, COSV52781671, COSV52788391; called by muse, mutect2, varscan2
- FASN | c.1231C>G p.P411A | Missense Mutation (SNP) | VAF 504/995 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV60755297; called by muse, mutect2, varscan2
- GABRA3 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 233/233 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1453531103, COSV100942994, COSV64798236; called by muse, mutect2, varscan2
- GEMIN8 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 382/802 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763460989; called by muse, mutect2, varscan2
- GPC1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 43/908 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99882855; called by muse, mutect2
- HS3ST3A1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 46/984 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754668033; called by muse, mutect2
- LTB4R | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 341/369 reads (92%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.474); catalogued as COSV51865726; called by muse, mutect2, varscan2
- NOS1 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 292/573 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1253013686, COSV57620440; called by muse, mutect2, varscan2
- NYAP2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs562957302, COSV56003370; called by muse, mutect2, varscan2
- OR51B4 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV66517209; called by muse, mutect2
- PDILT | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 169/296 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV56701795; called by muse, mutect2, varscan2
- SCG3 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs903703713, COSV55021042, COSV55021257, COSV99591009; called by muse, mutect2, varscan2
- SCML2 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 180/340 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52625879; called by muse, mutect2, varscan2
- SLC4A11 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 263/574 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs199724748; called by muse, mutect2, varscan2
- SLCO1B1 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 78/171 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs376060151; called by muse, mutect2, varscan2
- SMAD5 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.034); catalogued as rs780577486; called by muse, mutect2, varscan2
- TIMD4 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 154/332 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs141557472, COSV50855913; called by muse, mutect2, varscan2
- TOGARAM2 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 178/333 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750782855, COSV101091521; called by muse, mutect2, varscan2
- UTP14A | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs748046320; called by muse, mutect2, varscan2
- ZNF735 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs183236398, COSV70036120, COSV70036138; called by muse, mutect2, varscan2
- ANKRD24 | c.1232C>T p.T411I | Missense Mutation (SNP) | VAF 21/667 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARHGAP27 | c.1301A>C p.D434A (on ENST00000428638 / NM_001282290.1; = p.D93A on NM_199282.3) | Missense Mutation (SNP) | VAF 260/536 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ARSL | c.25T>A p.L9M | Missense Mutation (SNP) | VAF 174/427 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- BCORL1 | c.1424C>A p.T475N | Missense Mutation (SNP) | VAF 25/843 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2
- C9 | c.56T>A p.L19H | Missense Mutation (SNP) | VAF 154/288 reads (53%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- CADPS2 | c.1964T>C p.L655S | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CAMKK1 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 402/830 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); called by muse, mutect2
- CAPZA3 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.683); called by muse, mutect2
- CHRM1 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 290/623 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CROCC | c.5074C>T p.Q1692* | Nonsense Mutation (SNP) | VAF 150/311 reads (48%) | called by muse, mutect2, varscan2
- CRY1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 381/807 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- DHX40 | c.1742G>T p.R581M | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH12 | c.8922A>T p.E2974D (on ENST00000351747; = p.E3842D on NM_001366028.2) | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- DNAH14 | c.3123A>T p.K1041N (on ENST00000445597; = p.K1425N on NM_001367479.1) | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DTX3 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 355/745 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- EFCAB5 | c.2363C>T p.T788I | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FBF1 | c.2428G>A p.A810T (on ENST00000586717; = p.A824T on NM_001319193.1) | Missense Mutation (SNP) | VAF 337/715 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FLG | c.9120T>G p.H3040Q | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by mutect2, varscan2
- FOLR1 | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 51/525 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); called by muse, mutect2
- GMEB2 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 94/1077 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2
- HOOK3 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HTR3E | c.1193C>A p.A398E (on ENST00000415389 / NM_001256613.1; = p.A413E on NM_182589.2) | Missense Mutation (SNP) | VAF 252/475 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HUWE1 | c.10569T>G p.I3523M | Missense Mutation (SNP) | VAF 300/538 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- INHBE | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 309/675 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- LRP2 | c.12459A>C p.G4153= | Splice Region (SNP) | VAF 103/210 reads (49%) | called by muse, mutect2, varscan2
- MARCKSL1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 154/787 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MCM8 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- MTCL1 | c.5586A>C p.L1862F (on ENST00000306329 / NM_001378206.1; = p.L1543F on NM_015210.4) | Missense Mutation (SNP) | VAF 285/641 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- MTMR1 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 109/447 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- NEK11 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEXMIF | c.3332A>T p.K1111I | Missense Mutation (SNP) | VAF 237/560 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NOX5 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 177/411 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OTULINL | c.974A>C p.D325A | Missense Mutation (SNP) | VAF 194/372 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- PBXIP1 | c.175_178+2del p.X59_splice | Splice Site (DEL) | VAF 205/462 reads (44%) | called by mutect2, pindel*, varscan2*
- PICALM | c.1217A>G p.H406R | Missense Mutation (SNP) | VAF 115/231 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLAAT1 | c.185G>T p.C62F | Missense Mutation (SNP) | VAF 306/773 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNMA6E | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 398/1109 reads (36%) | SIFT tolerated (0.28); called by muse, varscan2
- SEC13 | c.512C>T p.P171L (on ENST00000350697 / NM_183352.3; = p.P174L on NM_030673.4) | Missense Mutation (SNP) | VAF 181/349 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHCBP1L | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SP110 | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- SULF2 | c.644C>G p.P215R | Missense Mutation (SNP) | VAF 364/692 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- SVBP | c.142G>C p.E48Q | Missense Mutation (SNP) | VAF 144/354 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYT10 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.286); called by mutect2, varscan2
- UBL7 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 197/436 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR77 | c.564+1G>C p.X188_splice | Splice Site (SNP) | VAF 163/355 reads (46%) | called by muse, mutect2, varscan2
- ZXDC | c.2137G>T p.G713C | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACVRL1 | c.888C>T p.P296= | Silent (SNP) | VAF 422/855 reads (49%) | catalogued as rs776879586; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1584G>A p.E528= | Silent (SNP) | VAF 372/740 reads (50%) | called by muse, mutect2, varscan2
- ADH7 | c.597C>G p.G199= | Silent (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- ALPP | c.783G>A p.A261= | Silent (SNP) | VAF 179/613 reads (29%) | catalogued as rs749165151; called by muse, mutect2, varscan2
- ANXA9 | c.99C>T p.G33= | Silent (SNP) | VAF 221/505 reads (44%) | called by muse, mutect2, varscan2
- BRCA2 | c.8667A>C p.A2889= | Silent (SNP) | VAF 147/407 reads (36%) | called by muse, mutect2, varscan2
- C3orf20 | c.510C>G p.T170= | Silent (SNP) | VAF 136/330 reads (41%) | called by muse, mutect2, varscan2
- CATSPERE | c.693C>A p.I231= | Silent (SNP) | VAF 146/308 reads (47%) | called by muse, mutect2, varscan2
- CRYM | c.144C>T p.T48= | Silent (SNP) | VAF 58/455 reads (13%) | called by muse, mutect2, varscan2
- EP300 | c.819G>A p.Q273= | Silent (SNP) | VAF 196/196 reads (100%) | catalogued as rs1291106008; called by muse, mutect2, varscan2
- GUCY1A1 | c.1824G>A p.E608= | Silent (SNP) | VAF 160/160 reads (100%) | catalogued as COSV56650456; called by muse, mutect2, varscan2
- HECTD4 | c.10134C>T p.D3378= | Silent (SNP) | VAF 458/911 reads (50%) | catalogued as rs761068239, COSV66387587; called by muse, mutect2, varscan2
- IGKC | c.147G>A p.S49= | Silent (SNP) | VAF 231/431 reads (54%) | catalogued as rs749487405; called by muse, mutect2, varscan2
- KIF1A | c.3753G>A p.A1251= (on ENST00000320389 / NM_001379639.1; = p.A1243= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 183/463 reads (40%) | catalogued as rs371203997; called by muse, mutect2, varscan2
- KIF26A | c.2289C>T p.A763= | Silent (SNP) | VAF 534/1078 reads (50%) | catalogued as rs1253999715; called by muse, mutect2, varscan2
- KRT26 | c.1401A>C p.A467= | Silent (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- LVRN | c.393G>A p.V131= | Silent (SNP) | VAF 304/677 reads (45%) | catalogued as COSV63497652; called by muse, mutect2, varscan2
- LYSMD4 | c.570T>C p.S190= (on ENST00000409796 / NM_001284417.2; = p.S191= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/616 reads (8%) | called by muse, mutect2
- MBOAT7 | c.408G>A p.K136= | Silent (SNP) | VAF 327/749 reads (44%) | called by muse, mutect2, varscan2
- OR5F1 | c.720G>A p.T240= | Silent (SNP) | VAF 134/310 reads (43%) | catalogued as rs540902518, COSV53546569; called by muse, varscan2
- OR5H2 | c.48G>A p.E16= | Silent (SNP) | VAF 62/153 reads (41%) | called by muse, mutect2, varscan2
- OR5M10 | c.315C>T p.I105= | Silent (SNP) | VAF 126/311 reads (41%) | catalogued as rs528316710, COSV73242361; called by muse, mutect2, varscan2
- PCLO | c.9924G>A p.E3308= | Silent (SNP) | VAF 151/559 reads (27%) | called by muse, mutect2, varscan2
- PLCH1 | c.2778C>T p.A926= (on ENST00000340059 / NM_001130960.2; = p.A918= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 224/407 reads (55%) | called by muse, mutect2, varscan2
- PLOD1 | c.729C>T p.N243= | Silent (SNP) | VAF 177/430 reads (41%) | catalogued as rs567164584, COSV52140360; called by muse, mutect2, varscan2
- PRR36 | c.1941C>T p.A647= | Silent (SNP) | VAF 291/545 reads (53%) | called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.903C>T p.H301= (on ENST00000352766; = p.H178= on NM_181334.5) | Silent (SNP) | VAF 375/375 reads (100%) | catalogued as rs753869236; called by muse, mutect2, varscan2
- SCN3A | c.5043A>G p.K1681= | Silent (SNP) | VAF 32/369 reads (9%) | called by muse, mutect2
- SCN9A | c.513C>T p.I171= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as COSV57601600; called by muse, mutect2, varscan2
- SEC63 | c.1879C>T p.L627= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as rs1263997622, COSV64599459; called by muse, mutect2, varscan2
- SHROOM4 | c.1632T>A p.T544= | Silent (SNP) | VAF 66/1046 reads (6%) | called by muse, mutect2
- TMEM52B | c.390C>G p.S130= (on ENST00000381923 / NM_001079815.1; = p.S110= on NM_153022.4) | Silent (SNP) | VAF 28/996 reads (3%) | called by muse, mutect2
- TMPRSS4 | c.384C>T p.F128= | Silent (SNP) | VAF 229/494 reads (46%) | catalogued as rs752005139, COSV71109854; called by muse, mutect2, varscan2
- TTLL2 | c.1677T>A p.V559= | Silent (SNP) | VAF 253/562 reads (45%) | called by muse, mutect2, varscan2
- UGT2B28 | c.759T>G p.A253= | Silent (SNP) | VAF 91/91 reads (100%) | called by muse, mutect2, varscan2
- WNK2 | c.5223G>A p.P1741= (on ENST00000297954 / NM_001282394.1; = p.P1704= on NM_006648.3) | Silent (SNP) | VAF 324/665 reads (49%) | catalogued as rs1382275162, COSV52939460; called by muse, mutect2, varscan2
- ZAN | c.7662G>A p.Q2554= | Silent (SNP) | VAF 278/788 reads (35%) | catalogued as rs781246138, COSV100770466; called by muse, mutect2, varscan2
- ZC3H7A | c.531G>A p.A177= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs778629611, COSV63268868, COSV63269808; called by muse, mutect2, varscan2
- ZNF544 | c.357T>A p.S119= | Silent (SNP) | VAF 178/386 reads (46%) | called by muse, mutect2, varscan2
- ACSL5 | c.-78G>T | 5'UTR (SNP) | VAF 100/393 reads (25%) | catalogued as COSV61132934; called by muse, mutect2, varscan2
- CTBP2 | c.58+12542C>A | Intron (SNP) | VAF 46/554 reads (8%) | called by muse, mutect2
- FAM98B | chr15:38484507 A>G | 3'Flank (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- MBLAC2 | c.454+35G>C | Intron (SNP) | VAF 345/635 reads (54%) | called by muse, mutect2, varscan2
